Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3877, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3877-01A (Primary Tumor).

Diagnosis/ diagnoses

Resected section of colon (transverse colon) with a colon carcinoma characterized histologically as a moderately differentiated, partially mucinous colorectal adenocarcinoma, located at the base of a tubulovillous adenoma with severe epithelial dysplasia (synonymous: profound intraepithelial neoplasia), extending a max of 5 cm to a resection margin and measuring 2 cm in diameter at the widest point. Invasive spreading of the tumor to the submucosa level.

Located 4 cm from the same resection margin there is a microscopically small section or remains of an adenoma of the colon mucosa, tubular in form and with slight epithelial dysplasia (synonym: mild intraepithelial neoplasia). In addition, in the centre of the preparation there is a microscopically small tubular adenoma of the colon mucosa or remains of an adenoma with moderate epithelial dysplasia (synonym: mild intraepithelial neoplasia).

Oral and aboral resection margins are tumor-free as is the greater omentum.

18 mesocolic lymph nodes are tumor-free with uncharacteristic reactive lesions.

Therefore the tumor stage is pT1 pN0 (0/18) L0 V0 R0; G2

Source: NCI Genomic Data Commons file d8481100-38b4-401b-9927-b036e0a312f8 (TCGA-AA-3877.241490A3-7FD3-48F2-94D3-8CABB776E24B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).